CGCI case BLGSP-71-23-00437 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f0f6f26a-2650-47ad-952f-43af9914b7ba

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 74.2 years (27,115 days); Year of diagnosis: 2015; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,362 days (3.7 years); Ann Arbor extranodal involvement: No; Max tumor bulk site: Axillary lymph nodes.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 1,362 days (3.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Negative; Specialized molecular test: Ki-67 > 90%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC (IHC): Positive.
- Lactate Dehydrogenase 338 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Risk factors: Hashimoto's Thyroiditis.
- Day 0: Comorbidities: Hashimoto's Thyroiditis.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00437-01A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-23-00437-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00437-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00437-01-CD3: Tissue microarray coordinates: C1,D4,A6.
  Slide BLGSP-71-23-00437-01-CD10: Tissue microarray coordinates: C1,D4,A6.
  Slide BLGSP-71-23-00437-01-CD20: Tissue microarray coordinates: C1,D4,A6.
  Slide BLGSP-71-23-00437-01-BCL2: Tissue microarray coordinates: C1,D4,A6.
  Slide BLGSP-71-23-00437-01-HE-1: Tissue microarray coordinates: C1,D4,A6.
  Slide BLGSP-71-23-00437-01-BCL6: Tissue microarray coordinates: C1,D4,A6.
  Slide BLGSP-71-23-00437-01-Ki67: Tissue microarray coordinates: C1,D4,A6.
- Sample BLGSP-71-23-00437-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00437-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 25.
  Slide BLGSP-71-23-00437-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease, History immunological diseases: History immunological disease: Hashimoto's Thyroiditis.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Days from index date to tumor sample procurement: -6; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 338; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: c-myc.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
